Somatic mutation profile of tumor specimen TCGA-AB-2899-03A (aliquot TCGA-AB-2899-03A-01W-0733-08) from TCGA case TCGA-AB-2899, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.1 years (27,787 days).
Specimen TCGA-AB-2899-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e71a236-3072-40d9-9c07-e051d70cdbca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2899-11A (Solid Tissue Normal), aliquot TCGA-AB-2899-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91932fc6-fcf0-4f0f-98ff-9bc2d8f53bf5

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.403A>G p.R135G (on ENST00000344691 / NM_001001890.3; = p.R162G on NM_001754.5) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519751, COSV55867213; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ALG13 | c.3260C>T p.P1087L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV52643592; called by muse, mutect2, varscan2
- DUSP1 | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV53320895; called by muse, mutect2, varscan2
- LDHAL6A | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99323903; called by muse, mutect2
- OIT3 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs144779514; called by muse, mutect2, varscan2
- QRICH2 | c.4451A>T p.D1484V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53156716, COSV53158029; called by muse, mutect2, varscan2
- UMOD | c.840dup p.E281Rfs*18 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs774365088; called by mutect2, pindel
- MBD5 | c.2940G>A p.Q980= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV68698612; called by muse, mutect2, varscan2
- OPN5 | c.912C>T p.I304= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as COSV55247071; called by muse, varscan2
